Somatic mutation profile of tumor specimen TARGET-10-PAUBRD-09A (aliquot TARGET-10-PAUBRD-09A-01D) from TARGET case TARGET-10-PAUBRD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,755 days).
Specimen TARGET-10-PAUBRD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b973baad-412d-4caf-952a-35d1a42719d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUBRD-10A (Blood Derived Normal), aliquot TARGET-10-PAUBRD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2b71c17-3318-42b3-b1fb-12028ac83a16

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CD | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 62/197 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs397518423, CM067447, COSV63126880; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH9 | c.9856C>A p.R3286S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52342960; called by muse, mutect2
- ITGA4 | c.3027C>A p.Y1009* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV59203942; called by muse, mutect2, varscan2
- JAKMIP1 | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201482171, COSV51523091; called by muse, varscan2
- PCLO | c.13313G>A p.R4438H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs773610201, COSV61618185; called by muse, mutect2, varscan2
- PRDM9 | c.1669T>G p.C557G | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1169051300, COSV57003114; called by muse, mutect2, varscan2
- SMOC2 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1000571767, COSV62434372; called by muse, mutect2, varscan2
- TTN | c.20596T>C p.C6866R (on ENST00000591111; = p.C5939R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | PolyPhen probably damaging (0.944); catalogued as rs1295622488, COSV59907309; called by muse, mutect2, varscan2
- BEND3 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2
- KLK6 | c.195dup p.P66Tfs*11 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- MTHFD2 | c.758C>A p.A253D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RUNX2 | c.195_197dup p.Q71dup | In Frame Ins (INS) | VAF 21/108 reads (19%) | called by mutect2, pindel, varscan2
- TRAV41 | c.290C>A p.T97K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PRKCG | c.18C>A p.P6= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, varscan2
- RUNX2 | c.198G>A p.Q66= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as rs748186399; called by muse, varscan2
- TOR1A | c.30G>T p.L10= | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
